Gene-level copy-number profile of tumor specimen C3N-06054-02 from CPTAC case C3N-06054, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 83.9 years (30,648 days).
Specimen C3N-06054-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e2148fc-2c79-4b52-9a0e-965a032d0d33.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06054-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/3e37088f-95d6-406d-8fd9-b2db973677de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 617; copy number 1: 11,030; copy number 2: 41,390; copy number 3: 3,050; copy number 4: 2,228; copy number 5: 360; copy number 6: 122; copy number 7: 51; copy number 8: 40; copy number 9: 22.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,990,496–22,552,156, 105 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 595 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:64,971,772–65,023,310, 3 genes, copy number 5: ZNF117, ERV3-1, RNU6-1229P.
- chr7:66,087,761–66,607,107, 21 genes, copy number 5 (within-gene range 4–5): AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5.
- chr7:66,995,173–67,362,950, 9 genes, copy number 5–7 (within-gene range 4–7): TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr7:67,691,058–68,119,209, 5 genes, copy number 5: AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57.
- chr7:72,558,744–72,951,440, 9 genes, copy number 6 (within-gene range 4–6): TYW1B, MIR4650-2, AC211469.2, AC211469.1, RN7SL377P, SBDSP1, RN7SL625P, SPDYE7P, POM121.
- chr7:73,667,831–75,888,926, 69 genes, copy number 5 (broad region; genes not listed).
- chr7:75,996,338–76,650,897, 26 genes, copy number 5: STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2.
- chr7:81,489,204–81,691,406, 2 genes, copy number 5 (within-gene range 4–5): AC008163.1, DDX43P3.
- chr7:83,955,777–84,492,724, 1 gene, copy number 5: SEMA3A.
- chr7:86,216,785–88,202,889, 22 genes, copy number 5: SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22.
- chr7:88,420,167–89,338,528, 11 genes, copy number 5: AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:95,359,872–95,615,132, 8 genes, copy number 5: PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4.
- chr7:97,851,677–98,252,232, 19 genes, copy number 6: ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1.
- chr7:123,230,120–123,230,741, 1 gene, copy number 6: LYPLA1P1.
- chr7:125,917,871–128,092,609, 23 genes, copy number 5–6 (within-gene range 3–8): AC003975.1, AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1, MIR592, GRM8-AS1, PRELID3BP10, ZNF800, AC000123.2, AC000123.1, AC000123.3, AC000124.1, GCC1, ARF5, FSCN3, PAX4, AC073934.1, SND1, AC006529.1.
- chr7:128,533,652–129,057,239, 34 genes, copy number 6–8: AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1, CALU, RN7SL81P, OPN1SW, CCDC136, FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB, AC025594.1, IRF5, AC025594.2, TNPO3, RN7SL306P, ODCP, TPI1P2.
- chr7:130,070,534–130,791,724, 28 genes, copy number 5–6: KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5.
- chr7:130,822,868–130,823,511, 2 genes, copy number 5: AC016831.2, H4P1.
- chr7:132,123,332–132,648,688, 3 genes, copy number 5: PLXNA4, AC018643.1, AC011625.1.
- chr7:134,127,299–135,748,813, 33 genes, copy number 5: LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A.
- chr7:137,381,037–141,480,380, 83 genes, copy number 5–8 (broad region; genes not listed).
- chr7:143,851,375–145,681,369, 42 genes, copy number 5–8 (within-gene range 4–8): TCAF1, OR2F2, OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1, OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1, ARHGEF5, NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1.
- chr18:508,568–1,310,018, 26 genes, copy number 5 (within-gene range 4–5): LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3.
- chr18:3,025,069–3,478,978, 17 genes, copy number 5: AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,878,058–3,897,069, 3 genes, copy number 6 (within-gene range 4–6): DLGAP1-AS3, MIR6718, RNU6-831P.
- chr22:41,045,497–41,529,273, 22 genes, copy number 9 (within-gene range 2–9): Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A.
- chr22:46,006,616–46,054,144, 4 genes, copy number 7 (within-gene range 3–7): BX537318.2, BX537318.1, LINC00899, PRR34.
- chr22:46,360,834–46,537,620, 2 genes, copy number 8: CELSR1, AL031597.1.
- chr22:47,612,231–48,058,275, 6 genes, copy number 5: LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2.
- chr22:48,448,890–48,451,217, 1 gene, copy number 5: Z82249.1.
- chr22:49,414,524–49,853,364, 17 genes, copy number 5: C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2.
- chr22:50,089,879–50,161,690, 1 gene, copy number 5 (within-gene range 3–5): MOV10L1.
- chr22:50,170,731–50,628,173, 36 genes, copy number 5: PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA.
- chr22:50,735,825–50,801,309, 6 genes, copy number 6: AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 8,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
